Surgical pathology report (de-identified scan), TCGA case TCGA-B8-5552, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site UNC, specimen TCGA-B8-5552-01B (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

Case Number : [REDACTED]
[REDACTED]

Surgical Pathology Report

Diagnosis:

Right kidney, right hand assisted laparoscopic nephrectomy

Histologic tumor type/subtype: renal cell carcinoma, clear cell type

Sarcomatoid features: not identified

Histologic grade (if applicable): Fuhrman nuclear grade 2

Tumor size (greatest dimension): 5.4 cm

Tumor focality: focal

Extent of tumor invasion (if present specify if macroscopic or microscopic):

Capsular invasion/perirenal adipose tissue: not identified

Gerota's fascia: not identified

Renal sinus: not identified

Major veins (renal vein or segmental branches, IVC): not identified

Ureter: not identified

Venous (large vessel): not identified

Lymphatic (small vessel): not identified

Histologic assessment of surgical margins:

Gerota's fascia (nephrectomy): negative

Renal vein (nephrectomy): negative

Ureter (nephrectomy): negative

Adrenal gland: not present

Lymph nodes: none identified

AJCC Staging:

pT1b

pNx

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Comment:

The frozen section diagnosis is confirmed.

Intraoperative Consult Diagnosis:

Frozen section was requested by [REDACTED]

FSA1: Right kidney, excision

- Clear cell renal cell carcinoma

Frozen Section Pathologist:

Clinical History:

right renal mass.

Gross Description:

The specimen was opened in the OR and was a 266 gram 17.0 x 9.5 x 5.3 cm kidney. The serosal surface was inked green. Bivalve of the kidney demonstrated a well-circumscribed cystic and solid mass, 5.4 x 3.5 x 2.5 cm. Representative sections of mass submitted in FSA1.

Specimen fixation: Formalin

[page 2 of 3]
Type of specimen: Laparoscopic nephrectomy
Side of specimen: Right

Size and weight of specimen: 266 grams; 17.0 x 9.5 x 5.3 cm

Orientation: The perirenal soft tissue is inked green.

Presence/absence of adrenal gland: Absent

Tumor site: Mass is present adjacent to the right lower pole of pyelocalyceal system .

Tumor description: The mass is well-circumscribed with a surrounding pseudocapsule. Cut sections demonstrate a yellow/tan cystic and solid cut surface. Possible areas of necrosis are identified.

Tumor size: 5.4 x 3.5 x 2.5 cm.

Presence/absence of multicentricity: Absent

Confinement/non-confinement to the kidney: Confined, closest area is 0.9 cm from medial lower pole renal parenchyma.

Extent of invasion:

Perirenal adipose tissue: Not grossly involved

Gerota' s fascia: Not grossly involved

Renal vein: Not grossly involved

Ureter: Not grossly involved

Renal Sinus: Tumor abuts renal sinus grossly, defer to light microscopy

Pelviccaliceal: Grossly adjacent to the right lower pole pelviccaliceal system

Adrenal: N/A

Other organs: N/A

Surgical margins:

Perirenal adipose tissue: Negative

Renal vein: Negative

Renal artery: Negative

Ureter: Negative

Description of kidney away from tumor: The rest of the right renal parenchyma is normal in appearance without additional masses, atrophy or scarring.

Hilar lymph nodes: Not present

Other significant findings: None

Tissue submitted for special investigations: Yes, per tissue procurement.

Digital picture: No

Block Summary:

A1 - Section of ureter vein and artery margins

A2 - Mass in relation to hilar vessels

A3 - Mass in relation to hilar vessels

A4 - Mass in relation to closest green inked surgical margin

A5 - Mass in relation to collecting system

[page 3 of 3]
A6 - Mass in relation to collecting system and green inked renal capsule

A7 - Mass in relation to pyelocalyceal system

A8 - Grossly normal kidney

Light Microscopy:

Light microscopic examination is performed by

Signature

Resident Physician:

Attending Pathologist: I have personally conducted the evaluation of the above specimens and have rendered the above diagnosis(es).

Source: NCI Genomic Data Commons file 905336f4-47ed-486e-9022-554af6c62ecd (TCGA-B8-5552.F2D158CA-EEBD-44DA-A8C0-294B7577E86F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).